Somatic mutation profile of tumor specimen TARGET-30-PAIXNC-01A (aliquot TARGET-30-PAIXNC-01A-01W) from TARGET case TARGET-30-PAIXNC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 2.0 years (723 days).
Specimen TARGET-30-PAIXNC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8eeb749d-be0d-4b3e-a19d-a205438175f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAIXNC-10A (Blood Derived Normal), aliquot TARGET-30-PAIXNC-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cf6020d-51d6-4305-946b-6b3308057826

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, In Frame Del 1, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.3764T>C p.L1255P | Missense Mutation (SNP) | VAF 78/407 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as COSV67016831; called by muse, mutect2, varscan2
- ACVR1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 233/543 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as COSV55118893; called by muse, mutect2, varscan2
- CASP8AP2 | c.860A>C p.H287P | Missense Mutation (SNP) | VAF 70/413 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52746912; called by muse, mutect2, varscan2
- CDH10 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV52577280, COSV52580482; called by muse, mutect2, varscan2
- CEP250 | c.6024C>G p.C2008W | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61170014; called by muse, mutect2, varscan2
- GOLGA3 | c.1283C>G p.A428G | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52631003; called by muse, mutect2, varscan2
- KRT6C | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 118/298 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as rs761980436, COSV52877654; called by muse, mutect2, varscan2
- NTRK1 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV62324129; called by muse, mutect2, varscan2
- PLCH1 | c.2431G>C p.V811L (on ENST00000340059 / NM_001130960.2; = p.V823L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58196901, COSV58207524; called by muse, mutect2, varscan2
- RNF128 | c.1021C>T p.P341S (on ENST00000255499 / NM_194463.2; = p.P315S on NM_024539.3) | Missense Mutation (SNP) | VAF 23/437 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs890338762; called by muse, mutect2
- SLC1A2 | c.1678T>A p.S560T | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53521320; called by muse, mutect2, varscan2
- SRCAP | c.539A>G p.E180G | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52672450; called by muse, mutect2, varscan2
- XRRA1 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773395555, COSV58497760; called by muse, mutect2, varscan2
- OR6N1 | c.873C>A p.S291R | Missense Mutation (SNP) | VAF 130/1342 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRPM3 | c.3430G>T p.E1144* (on ENST00000357533 / NM_001366142.2; = p.E999* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 17/449 reads (4%) | called by muse, mutect2
- USP48 | c.1793_1795del p.S598del | In Frame Del (DEL) | VAF 60/170 reads (35%) | called by pindel, varscan2
- CHRD | c.855C>T p.A285= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV52607833; called by muse, mutect2, varscan2
- GSPT2 | c.198G>A p.A66= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1557348799, COSV61214292; called by muse, mutect2
- NLRP4 | c.2142C>G p.L714= | Silent (SNP) | VAF 72/164 reads (44%) | catalogued as rs138595435; called by muse, mutect2, varscan2
- PON1 | c.18G>A p.A6= | Silent (SNP) | VAF 70/177 reads (40%) | catalogued as COSV55931844; called by muse, mutect2, varscan2
